Somatic mutation profile of tumor specimen TCGA-FI-A2CX-01A (aliquot TCGA-FI-A2CX-01A-11D-A17D-09) from TCGA case TCGA-FI-A2CX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 82.7 years (30,224 days).
Specimen TCGA-FI-A2CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cb77cca-cd58-44de-ba70-272da73cb3cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FI-A2CX-10A (Blood Derived Normal), aliquot TCGA-FI-A2CX-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dbd48f6-7e37-4b72-b5b5-0e16ebfcf059

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C14orf39 | c.1333T>A p.F445I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.344); catalogued as COSV100407383; called by muse, mutect2, varscan2
- CHRD | c.1881del p.S628Pfs*2 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as COSV52608195; called by mutect2, pindel
- KCNN3 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.049); catalogued as rs576968004, COSV99677749; called by muse, varscan2
- LDLRAD4 | c.267C>A p.Y89* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100762037, COSV100762046; called by muse, mutect2, varscan2
- LRFN2 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs149554730; called by muse, mutect2, varscan2
- OR56A1 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100360413; called by muse, mutect2, varscan2
- PPIG | c.850A>G p.R284G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs1424300948, COSV99644312; called by mutect2, varscan2
- RBMS3 | c.744+1G>A p.X248_splice | Splice Site (SNP) | VAF 5/63 reads (8%) | catalogued as COSV99820074; called by muse, mutect2
- SLC6A17 | c.1615G>C p.E539Q | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100521149; called by muse, mutect2
- TAGAP | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.32); catalogued as rs200038955, COSV100487319; called by muse, mutect2, varscan2
- ZBTB47 | c.1415T>A p.F472Y | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99234006; called by muse, mutect2, varscan2
- ZNF558 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100037877; called by muse, mutect2, varscan2
- COL5A1 | c.2738G>A p.G913D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CMSS1 | c.99A>G p.E33= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV101375499; called by muse, mutect2
- OLFM3 | c.1263C>A p.S421= (on ENST00000338858 / NM_001288821.1; = p.S401= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100129011, COSV58805039; called by muse, mutect2
- SH3TC1 | c.612C>T p.S204= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV99794575; called by muse, mutect2
